Somatic mutation profile of tumor specimen TCGA-05-4390-01A (aliquot TCGA-05-4390-01A-02D-1753-08) from TCGA case TCGA-05-4390, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.7 years (21,430 days).
Specimen TCGA-05-4390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e99bf12-cf11-4b19-b4e7-fd81306cc2fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4390-10A (Blood Derived Normal), aliquot TCGA-05-4390-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f09497c7-2fbe-4355-81c7-bfa2dea95b9a

The open-access MAF lists 597 somatic variants for this specimen: 457 protein-altering or splice-affecting, 127 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 388, Silent 127, Nonsense Mutation 27, Frame Shift Del 20, Splice Site 10, Splice Region 7, Intron 6, Frame Shift Ins 4, RNA 4, 3'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.5935G>T p.E1979* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as rs1555111763, COSV53741126; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3557T>C p.I1186T | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55950145; called by muse, mutect2, varscan2
- ABCD2 | c.1979C>A p.S660Y | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58051486; called by muse, mutect2, varscan2
- ACAP1 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV50135550; called by muse, mutect2, varscan2
- ACSM2B | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV61657656, COSV61659796; called by muse, mutect2, varscan2
- ADAMTS10 | c.1700_1701insC p.S568Vfs*4 | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | catalogued as COSV99546790; called by mutect2, pindel*, varscan2
- ADAMTS2 | c.2501A>T p.Y834F | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52373872; called by muse, mutect2, varscan2
- ADAMTS5 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53178626; called by muse, mutect2, varscan2
- ADGRG4 | c.2966C>A p.S989Y | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV54955073; called by muse, varscan2
- ADGRG6 | c.2038G>C p.A680P | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51591113, COSV51600282; called by muse, mutect2, varscan2
- ADIPOR2 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63946195; called by muse, mutect2, varscan2
- AFF2 | c.3881T>A p.V1294D | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53987561; called by muse, mutect2, varscan2
- AFP | c.1022A>G p.Q341R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV56924980; called by muse, mutect2, varscan2
- AHSG | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99889974; called by mutect2, varscan2
- AKAP11 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50296424; called by muse, mutect2, varscan2
- AL121899.2 | c.2016G>T p.E672D | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV67350481; called by muse, mutect2, varscan2
- ALDH1B1 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66619628; called by muse, mutect2, varscan2
- ALMS1 | c.2107G>T p.D703Y | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52508773; called by muse, mutect2, varscan2
- ANKMY1 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56033484, COSV99803076; called by muse, mutect2, varscan2
- ANOS1 | c.1842+1G>T p.X614_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as COSV52918440, COSV99390771; called by muse, mutect2
- ANXA10 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63738907; called by muse, mutect2, varscan2
- AOC1 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62868353; called by muse, mutect2, varscan2
- APCS | c.271A>T p.S91C | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99661278; called by muse, mutect2, varscan2
- ARFGEF1 | c.4286G>T p.R1429I | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1214812941, COSV51607382; called by muse, mutect2
- ARHGAP20 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV52810331, COSV99505655; called by muse, mutect2, varscan2
- ARMCX2 | c.1532C>A p.A511E | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57529897; called by muse, mutect2, varscan2
- ARSJ | c.1789A>T p.T597S | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV59537686; called by muse, mutect2
- ATL1 | c.883A>T p.K295* | Nonsense Mutation (SNP) | VAF 10/141 reads (7%) | catalogued as COSV63296322; called by muse, mutect2
- ATM | c.8083G>A p.G2695S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555127166, COSV53741150, COSV53763120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.1838C>A p.A613D | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.187); catalogued as COSV59150275, COSV59150744; called by muse, mutect2, varscan2
- ATP11C | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV59563110; called by muse, mutect2, varscan2
- ATP2B3 | c.2644G>T p.V882L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV54840367, COSV54845765; called by muse, mutect2, varscan2
- ATXN7L3 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.715); catalogued as COSV66988910; called by muse, varscan2
- B4GALT5 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV65493505; called by muse, mutect2, varscan2
- BAZ2B | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV58599817; called by muse, mutect2, varscan2
- BCAN | c.1807G>T p.G603C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV61256678; called by muse, mutect2, varscan2
- BEND4 | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as rs890600469, COSV72469070; called by muse, mutect2, varscan2
- BIRC6 | c.8669G>T p.R2890L | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV70195753, COSV70198632; called by muse, mutect2, varscan2
- BRINP3 | c.2075C>A p.T692N | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV66522803; called by muse, mutect2, varscan2
- BRIP1 | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs587781819, COSV51998852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRS3 | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101036456, COSV65710943; called by muse, mutect2, varscan2
- BTAF1 | c.4675A>T p.K1559* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV56433098; called by muse, mutect2, varscan2
- BTBD11 | c.2058C>A p.N686K (on ENST00000280758 / NM_001018072.2; = p.N223K on NM_001017523.2) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as COSV55023487; called by muse, mutect2, varscan2
- BTK | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | catalogued as COSV58119622; called by muse, mutect2
- CACNA1S | c.429C>G p.N143K | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV62939042; called by muse, mutect2, varscan2
- CACNA2D3 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55535127, COSV55537315; called by muse, mutect2, varscan2
- CACNA2D4 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs868439220, COSV104383152, COSV54949447; called by muse, mutect2, varscan2
- CAD | c.3367G>T p.V1123L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53026371; called by muse, mutect2, varscan2
- CAPN10 | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54376280; called by muse, mutect2, varscan2
- CASQ2 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54770155; called by muse, mutect2, varscan2
- CCDC14 | c.1943C>A p.S648Y (on ENST00000488653; = p.S600Y on NM_022757.5) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100113120; called by muse, mutect2, varscan2
- CCDC171 | c.3839C>A p.P1280Q | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV66239459; called by muse, mutect2
- CCDC80 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.276); catalogued as COSV52816142, COSV52817338; called by muse, mutect2, varscan2
- CCDC93 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60121057; called by muse, mutect2, varscan2
- CDH9 | c.2149C>T p.H717Y | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV50276366; called by muse, mutect2, varscan2
- CDHR3 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV58416566; called by muse, mutect2, varscan2
- CDK20 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 171/224 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as COSV100308043; called by muse, mutect2, varscan2
- CEP192 | c.1527A>T p.R509S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV58063399; called by muse, mutect2, varscan2
- CES3 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs568963264, COSV57593378; called by muse, mutect2, varscan2
- CFAP44 | c.2620G>T p.V874L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV55611017; called by muse, mutect2
- CFAP69 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60185554; called by muse, mutect2, varscan2
- CHD4 | c.2409C>G p.I803M (on ENST00000357008 / NM_001363606.2; = p.I816M on NM_001273.5) | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58900103; called by muse, mutect2, varscan2
- CHD5 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs370035599, COSV52413396, COSV99312722; called by muse, mutect2, varscan2
- CHST2 | c.1286T>A p.V429E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58885373; called by muse, mutect2, varscan2
- CLSTN2 | c.1459C>A p.H487N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV71720590; called by muse, mutect2, varscan2
- CNTN1 | c.1469G>T p.R490I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.716); catalogued as COSV61639226; called by muse, mutect2, varscan2
- CNTN1 | c.2355G>T p.K785N | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61639232; called by muse, mutect2, varscan2
- COL15A1 | c.2182C>A p.P728T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV66644080; called by muse, mutect2, varscan2
- COL19A1 | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs199945062, COSV59571622; called by muse, mutect2, varscan2
- COL1A2 | c.2821C>T p.Q941* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV51957261; called by muse, mutect2, varscan2
- COL24A1 | c.4621C>A p.P1541T | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65305562; called by muse, mutect2, varscan2
- COL4A5 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.34); catalogued as COSV60360760, COSV60362063; called by muse, mutect2, varscan2
- COL4A5 | c.4523G>T p.S1508I | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60360772, COSV60370526; called by muse, mutect2, varscan2
- COL4A6 | c.4739T>A p.V1580E | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57865261; called by muse, mutect2, varscan2
- CORO6 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52171645; called by muse, mutect2, varscan2
- CRYBB2 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1023262728, COSV68005441; called by muse, mutect2, varscan2
- CSMD3 | c.2503C>A p.P835T (on ENST00000297405 / NM_001363185.1; = p.P731T on NM_052900.3) | Missense Mutation (SNP) | VAF 102/176 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52167266; called by muse, mutect2, varscan2
- CSTF2T | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV58656347; called by muse, mutect2, varscan2
- CTCFL | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV54773710; called by muse, mutect2, varscan2
- CTNNA2 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.14); catalogued as COSV58150038; called by muse, mutect2, varscan2
- CTPS1 | c.854G>T p.W285L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV65452313; called by muse, mutect2, varscan2
- DBF4 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.081); catalogued as COSV99719246; called by muse, varscan2
- DBF4 | c.1358T>A p.L453Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.216); catalogued as COSV99719248; called by muse, varscan2
- DBX2 | c.479C>A p.A160E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV60337432, COSV60339902; called by muse, mutect2, varscan2
- DCAF12L1 | c.287C>G p.T96R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.91); catalogued as rs1194686525, COSV64421709; called by muse, mutect2, varscan2
- DDC | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as CM149261, COSV63565009; called by muse, mutect2, varscan2
- DEFB115 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV68723099, COSV68723426; called by muse, mutect2, varscan2
- DEPDC5 | c.2027C>T p.P676L (on ENST00000400246; = p.P745L on NM_014662.5) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56696530; called by muse, mutect2, varscan2
- DGKI | c.623G>T p.R208M | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.971); catalogued as COSV55947911; called by muse, mutect2, varscan2
- DMD | c.9065C>A p.T3022N | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as COSV58907579; called by muse, mutect2, varscan2
- DOCK2 | c.3757-1G>A p.X1253_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV56955959; called by muse, mutect2, varscan2
- DOCK2 | c.4044C>A p.Y1348* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV56955969; called by muse, mutect2, varscan2
- DPYS | c.1552C>A p.H518N | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV60908275; called by muse, mutect2, varscan2
- DPYSL4 | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.401); catalogued as COSV58307093; called by muse, mutect2, varscan2
- DRD1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1218236198, COSV67104534; called by muse, mutect2, varscan2
- DSG2 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 106/154 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397516702, CM166750, COSV55198803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EARS2 | c.1275G>T p.W425C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV71942825; called by muse, mutect2, varscan2
- EBP | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV52141653; called by muse, mutect2
- EDAR | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM132000, COSV51502296; called by muse, mutect2, varscan2
- ENPP2 | c.1184C>A p.S395Y (on ENST00000075322 / NM_001040092.3; = p.S447Y on NM_006209.5) | Missense Mutation (SNP) | VAF 83/126 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV50012819, COSV50013928; called by muse, mutect2, varscan2
- EPHB3 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV57805641, COSV57806776; called by muse, mutect2, varscan2
- ERAS | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV54432715; called by muse, mutect2, varscan2
- ERBIN | c.1945C>T p.H649Y | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV52315306; called by muse, mutect2, varscan2
- ERICH3 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV58605596; called by muse, mutect2, varscan2
- F8 | c.6956C>G p.P2319R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM080273, CM1314829, CM910151, COSV100371734, COSV57705047; called by muse, mutect2, varscan2
- F8 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64270383, COSV64272864; called by muse, mutect2, varscan2
- FAM169A | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV65846442; called by muse, mutect2, varscan2
- FAM189B | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as rs1255788115, COSV63219139; called by muse, mutect2, varscan2
- FAM71B | c.1367G>T p.R456I | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV57228864; called by muse, mutect2, varscan2
- FARP1 | c.2698C>G p.L900V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as COSV60336184; called by muse, mutect2
- FAT3 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV53082222, COSV53087184, COSV53104933; called by muse, mutect2, varscan2
- FBN2 | c.4252C>T p.Q1418* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV52509901; called by muse, mutect2, varscan2
- FBN2 | c.3062G>T p.R1021L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV52509922; called by muse, mutect2, varscan2
- FBXL7 | c.586T>A p.C196S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.109); catalogued as COSV61645319; called by muse, mutect2, varscan2
- FGF23 | c.540C>A p.S180R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV52975925, COSV52976963; called by muse, mutect2, varscan2
- FLG | c.8775T>G p.D2925E | Missense Mutation (SNP) | VAF 40/429 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV100911465; called by muse, mutect2, varscan2
- FLNA | c.5913C>G p.I1971M (on ENST00000369850 / NM_001110556.2; = p.I1963M on NM_001456.3) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV61042176; called by muse, mutect2, varscan2
- FLT1 | c.1818G>T p.K606N | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV56726493; called by muse, mutect2, varscan2
- FRY | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV66569457; called by muse, mutect2, varscan2
- FSTL5 | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60193370; called by muse, mutect2, varscan2
- FTO | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758990618, COSV51663899; called by muse, mutect2, varscan2
- GAB1 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53756325; called by muse, mutect2, varscan2
- GAB3 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV65819447; called by muse, mutect2, varscan2
- GABRA3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV64795195; called by muse, mutect2, varscan2
- GABRQ | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64781784; called by muse, mutect2, varscan2
- GLRA1 | c.776G>T p.S259I | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM104319, COSV51011935; called by muse, mutect2, varscan2
- GPR101 | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 138/346 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV99981366; called by muse, mutect2, varscan2
- GPR119 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV52275376, COSV99358605; called by muse, mutect2, varscan2
- GPR149 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 108/251 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67667066; called by muse, mutect2, varscan2
- GPR84 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57209579; called by muse, mutect2, varscan2
- GPRC5B | c.1109C>G p.P370R | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026268; called by muse, mutect2, varscan2
- GRIK2 | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV59732488; called by muse, mutect2, varscan2
- GRIN3A | c.1336A>G p.S446G | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV62453075; called by muse, mutect2, varscan2
- GRPR | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 142/437 reads (32%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV66669240; called by muse, mutect2, varscan2
- GTF2F1 | c.1427A>C p.K476T | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55532171; called by muse, mutect2
- GTF3C1 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV62240855; called by muse, mutect2, varscan2
- HCFC1 | c.2134-1G>A p.X712_splice | Splice Site (SNP) | VAF 30/64 reads (47%) | catalogued as COSV60071874; called by muse, mutect2
- HCFC2 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99982992; called by muse, mutect2
- HDX | c.1586C>G p.A529G | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52976151; called by muse, mutect2, varscan2
- HECTD4 | c.4824G>T p.R1608S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66391179; called by muse, varscan2
- HERC4 | c.2528G>T p.R843I (on ENST00000395198 / NM_022079.3; = p.R835I on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53270557; called by muse, mutect2, varscan2
- HIRA | c.3020G>T p.C1007F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV54274553; called by muse, mutect2, varscan2
- HIVEP3 | c.3335G>C p.G1112A | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV56014574; called by muse, mutect2, varscan2
- HMGB3 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100308487, COSV57485971; called by muse, mutect2, varscan2
- HOXB2 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752163608, COSV100344578; called by muse, mutect2, varscan2
- HROB | c.1561+2T>A p.X521_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | catalogued as COSV55369481; called by muse, mutect2, varscan2
- HS3ST1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136765; called by muse, mutect2, varscan2
- HTR1F | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs1315058773, COSV60389560; called by muse, mutect2, varscan2
- IBA57 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs1376244621, COSV64511041, COSV64511065; called by muse, mutect2, varscan2
- IL12RB2 | c.1038G>A p.K346= | Splice Region (SNP) | VAF 19/75 reads (25%) | catalogued as COSV52023083; called by muse, mutect2, varscan2
- IMPG2 | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368525575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IPO5 | c.1592A>T p.Y531F | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55154189; called by muse, mutect2, varscan2
- IPO8 | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV56241303; called by muse, mutect2
- IQCF2 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773281948, COSV100291027; called by muse, mutect2, varscan2
- ISOC1 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51491650; called by muse, mutect2, varscan2
- ITGA11 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200757549; called by muse, mutect2, varscan2
- ITPR1 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV56979314; called by muse, mutect2, varscan2
- JCHAIN | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV54658736; called by muse, mutect2, varscan2
- KANSL2 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV100770800, COSV100770904; called by muse, mutect2
- KCNB1 | c.2397C>A p.S799R | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV65567997; called by muse, mutect2, varscan2
- KCNH1 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1482880324, COSV55079618; called by muse, mutect2, varscan2
- KDM2B | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV100997373; called by muse, mutect2, varscan2
- KDM2B | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV100997374; called by muse, mutect2, varscan2
- KDM5C | c.877del p.E293Rfs*6 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | catalogued as COSV64769195; called by mutect2, pindel, varscan2
- KIF14 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV66261511; called by muse, mutect2, varscan2
- KIR3DL1 | c.1078C>A p.L360I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as COSV58490215; called by muse, varscan2
- KLK1 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.721); catalogued as COSV56826761; called by muse, mutect2, varscan2
- KLRF1 | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV54380769; called by muse, mutect2, varscan2
- KRT84 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57771546; called by muse, mutect2
- KRTAP5-11 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV59368874; called by muse, mutect2, varscan2
- LAIR2 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56621407; called by muse, mutect2, varscan2
- LAMA1 | c.4030A>T p.R1344* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as COSV67536260; called by muse, mutect2
- LAMA1 | c.2528G>T p.G843V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67536265; called by muse, mutect2, varscan2
- LAMA2 | c.9186C>A p.D3062E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV70345925; called by muse, mutect2, varscan2
- LAMB4 | c.4774C>A p.Q1592K | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52718114; called by muse, mutect2, varscan2
- LARP1B | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52797026; called by muse, mutect2, varscan2
- LDB2 | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV58768390; called by muse, mutect2
- LDLRAD4 | c.667A>C p.M223L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as COSV63336939; called by muse, mutect2
- LILRB2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs754528432, COSV58744319; called by muse, mutect2, varscan2
- LINGO2 | c.1142T>G p.M381R | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV58059396; called by muse, mutect2, varscan2
- LIPG | c.1037-2A>T p.X346_splice | Splice Site (SNP) | VAF 88/141 reads (62%) | catalogued as COSV54296000; called by muse, mutect2, varscan2
- LLCFC1 | c.332C>A p.T111K (on ENST00000458732; = p.T80K on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100787015; called by muse, mutect2, varscan2
- LRGUK | c.249_250insT p.E84* | Frame Shift Ins (INS) | VAF 33/108 reads (31%) | catalogued as COSV99604032; called by mutect2, pindel, varscan2
- LRRC15 | c.1538A>T p.E513V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV100752658; called by muse, mutect2, varscan2
- LRRC15 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV61651153; called by muse, mutect2, varscan2
- LRRC4C | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53424171; called by muse, mutect2, varscan2
- LTBP1 | c.4127C>A p.S1376* (on ENST00000404816 / NM_206943.4; = p.S1050* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as COSV55378760, COSV99698800; called by muse, mutect2, varscan2
- LTN1 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV63733645; called by muse, mutect2, varscan2
- LUM | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as rs368836782, COSV57129342; called by muse, mutect2, varscan2
- LUZP2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV61196874; called by muse, mutect2, varscan2
- MAGEB10 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63311082; called by muse, mutect2, varscan2
- MAGEB2 | c.751del p.D251Ifs*36 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as COSV100975658; called by mutect2, pindel, varscan2
- MAGEB3 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV64397030, COSV64397095; called by muse, mutect2, varscan2
- MAGED1 | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58515162; called by muse, mutect2, varscan2
- MAP2 | c.1285A>T p.S429C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); catalogued as rs1043905466, COSV52289455; called by muse, mutect2
- MAP3K19 | c.1030G>T p.V344F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59638460; called by muse, mutect2, varscan2
- MAPK4 | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs757297774, COSV101245355, COSV68541953; called by muse, mutect2, varscan2
- MAPKAP1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV56367193; called by muse, mutect2, varscan2
- MED12 | c.2305C>A p.H769N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs755014778, COSV61338663; called by muse, mutect2, varscan2
- MED16 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 65/92 reads (71%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV54126030; called by muse, mutect2, varscan2
- MICAL3 | c.3968T>G p.L1323R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV71588269; called by muse, mutect2, varscan2
- MIER2 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.393); catalogued as COSV53395462; called by muse, mutect2, varscan2
- MMP2 | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM161167, COSV54600901; called by muse, mutect2, varscan2
- MORC1 | c.2420C>A p.A807E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51719083, COSV51731709; called by muse, mutect2, varscan2
- MORF4L2 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as COSV64610962; called by muse, mutect2
- MROH2B | c.2519C>A p.P840Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68183422, COSV68186222; called by muse, mutect2, varscan2
- MRPL44 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51312568; called by muse, mutect2, varscan2
- MTG2 | c.1205A>T p.Q402L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV63693749; called by muse, mutect2, varscan2
- MTMR8 | c.1550T>A p.L517H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66393650; called by muse, mutect2, varscan2
- MUC2 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); catalogued as rs747688546; called by muse, mutect2
- MXRA5 | c.8003G>C p.R2668P | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV54230127, COSV54233510; called by muse, mutect2, varscan2
- MXRA5 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99476582; called by muse, mutect2, varscan2
- MYF6 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57351472; called by muse, mutect2, varscan2
- MYH11 | c.4038C>A p.N1346K | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.589); catalogued as COSV55551544; called by muse, mutect2, varscan2
- MYO5B | c.2044G>C p.G682R | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1401138978, COSV53217734, COSV99543874; called by muse, mutect2, varscan2
- MYO7B | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101268082; called by muse, mutect2, varscan2
- MYO9A | c.4108C>T p.R1370W | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs747290915, COSV61850362; called by muse, mutect2, varscan2
- MYOCD | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1392561541, COSV58502815; called by muse, mutect2, varscan2
- NAA25 | c.639G>T p.L213F | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55703998; called by muse, mutect2, varscan2
- NAP1L3 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59075103; called by muse, mutect2, varscan2
- NAV3 | c.5773G>T p.G1925C (on ENST00000397909 / NM_001024383.2; = p.G1903C on NM_014903.6) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV57076922; called by muse, mutect2, varscan2
- NCAM2 | c.1704G>T p.R568S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.464); catalogued as COSV53072135; called by muse, mutect2
- NEBL | c.512A>T p.H171L | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.073); catalogued as CM166247, COSV65799667; called by muse, mutect2, varscan2
- NELL1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54260363; called by muse, mutect2, varscan2
- NETO1 | c.1056C>G p.I352M | Missense Mutation (SNP) | VAF 64/81 reads (79%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as COSV55003381, COSV55005837; called by muse, mutect2, varscan2
- NFATC2 | c.1118C>A p.P373H | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.922); catalogued as COSV65355484; called by muse, mutect2, varscan2
- NFKB2 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1369716464, COSV50045315; called by muse, mutect2
- NINL | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54001961; called by muse, mutect2, varscan2
- NLGN1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV64332012; called by muse, mutect2, varscan2
- NLGN3 | c.2515C>A p.L839M (on ENST00000358741 / NM_181303.2; = p.L819M on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV62445939; called by muse, mutect2
- NLRC5 | c.5003+1G>T p.X1668_splice | Splice Site (SNP) | VAF 19/43 reads (44%) | catalogued as COSV52654450; called by muse, mutect2, varscan2
- NLRP5 | c.2129T>G p.V710G | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66764188; called by muse, mutect2, varscan2
- NLRP5 | c.2528A>T p.N843I | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV66764191, COSV66764231; called by muse, mutect2, varscan2
- NLRP8 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs145268550; called by muse, mutect2, varscan2
- NOLC1 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV64180352; called by muse, mutect2, varscan2
- NOS1 | c.2957C>A p.T986K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.817); catalogued as COSV57611463; called by muse, mutect2, varscan2
- NRXN2 | c.4130C>A p.T1377K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV55452243; called by muse, mutect2, varscan2
- NRXN3 | c.1682G>T p.R561M (on ENST00000335750 / NM_001330195.2; = p.R188M on NM_004796.6) | Missense Mutation (SNP) | VAF 102/420 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV59743304; called by muse, varscan2
- NUDT12 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50090908; called by muse, mutect2, varscan2
- NXNL2 | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT tolerated (0.48); PolyPhen benign (0.165); catalogued as COSV101018268; called by muse, mutect2, varscan2
- ODF2 | c.2368A>C p.N790H (on ENST00000434106 / NM_153433.2; = p.N766H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59407556; called by muse, mutect2
- OGDHL | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV65102137; called by muse, mutect2
- OLAH | c.238G>C p.D80H (on ENST00000378228 / NM_001039702.3; = p.D133H on NM_018324.3) | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65492241; called by muse, mutect2, varscan2
- OLFML2B | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54196033; called by muse, mutect2, varscan2
- OR2AK2 | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV63552274; called by muse, mutect2, varscan2
- OR2AK2 | c.892A>T p.T298S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV63552275; called by muse, mutect2, varscan2
- OR2L2 | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63552278; called by muse, mutect2, varscan2
- OR2T4 | c.756del p.I253Sfs*8 | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | catalogued as rs869053829; called by mutect2, pindel, varscan2
- OR2W1 | c.296T>C p.I99T | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs777525265, COSV65851572; called by muse, mutect2, varscan2
- OR2W3 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs201811838, COSV64456738; called by muse, mutect2
- OR4C46 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as rs1233021940, COSV60219138; called by muse, mutect2, varscan2
- OR4N5 | c.155A>T p.D52V | Missense Mutation (SNP) | VAF 114/497 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61320476; called by muse, mutect2, varscan2
- OR52A5 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56615031, COSV56615221; called by muse, mutect2, varscan2
- OR52K2 | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57835037; called by muse, mutect2, varscan2
- OR56A1 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57362478; called by muse, mutect2, varscan2
- OR5B12 | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV56904613, COSV56905295; called by muse, mutect2, varscan2
- OR5P2 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100271304, COSV61490337; called by muse, mutect2, varscan2
- OR5T2 | c.724del p.V242Wfs*10 | Frame Shift Del (DEL) | VAF 52/142 reads (37%) | catalogued as COSV57589438; called by mutect2, pindel, varscan2
- OR6N1 | c.183C>A p.H61Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58648217; called by muse, mutect2, varscan2
- OSM | c.350_351insA p.K119Qfs*46 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | catalogued as COSV99304121; called by mutect2, pindel, varscan2
- OTC | c.923C>A p.P308Q | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV50001507; called by muse, mutect2, varscan2
- OTOF | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs760054878, COSV55501865; called by muse, mutect2, varscan2
- PABPC3 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99879376; called by muse, varscan2
- PAK5 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 80/151 reads (53%) | catalogued as COSV62023013, COSV62026441; called by muse, mutect2, varscan2
- PARP14 | c.5074G>T p.V1692F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV71734608; called by muse, mutect2, varscan2
- PASD1 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV64855079; called by muse, mutect2, varscan2
- PCDH19 | c.2521C>A p.R841S (on ENST00000373034 / NM_001184880.2; = p.R794S on NM_020766.3) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); catalogued as COSV55262000, COSV55267122; called by muse, mutect2, varscan2
- PCDH9 | c.1964G>C p.R655P | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV60546646; called by muse, mutect2, varscan2
- PCDHGA7 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV53938268; called by muse, mutect2, varscan2
- PCDHGB3 | c.2348A>C p.D783A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV53938243; called by muse, mutect2, varscan2
- PCDHGB7 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV53938280; called by muse, mutect2, varscan2
- PCLO | c.10139G>T p.G3380V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV61632116; called by muse, mutect2, varscan2
- PDGFRB | c.151G>T p.V51F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV55804302, COSV55810156; called by muse, mutect2, varscan2
- PEG3 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV55632094; called by muse, mutect2, varscan2
- PGLYRP1 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.624); catalogued as COSV50516762; called by muse, mutect2, varscan2
- PIGS | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52024268; called by muse, mutect2, varscan2
- PILRB | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.167); catalogued as COSV60334228; called by muse, mutect2, varscan2
- PJA1 | c.1498G>A p.D500N (on ENST00000361478 / NM_145119.4; = p.D312N on NM_022368.5) | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV64053038; called by muse, varscan2
- PLCB4 | c.3493G>T p.A1165S (on ENST00000278655 / NM_182797.3; = p.S1177I on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as rs754295464, COSV53800246; called by muse, mutect2, varscan2
- PLCE1 | c.3633C>A p.S1211R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV53348732, COSV53358042; called by muse, mutect2, varscan2
- PLS3 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.068); catalogued as rs782090562, COSV56778150; called by muse, mutect2, varscan2
- PLXND1 | c.2559C>A p.S853R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.758); catalogued as COSV60712789; called by muse, mutect2, varscan2
- PNP | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64091936; called by muse, mutect2, varscan2
- PON3 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55699082; called by muse, mutect2, varscan2
- POTEE | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs772145185, COSV58225905; called by muse, mutect2, varscan2
- POTEM | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 151/708 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV101304844, COSV69152997; called by muse, varscan2
- PPM1L | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55570916, COSV99861564; called by muse, mutect2, varscan2
- PPP1R15A | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV52338842; called by muse, mutect2, varscan2
- PPP6R1 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 56/165 reads (34%) | catalogued as COSV69799652; called by muse, mutect2, varscan2
- PRKCH | c.632A>G p.H211R | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60647948; called by muse, mutect2, varscan2
- PRMT9 | c.940A>G p.R314G | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376530430; called by muse, mutect2, varscan2
- PSG9 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52484775; called by muse, mutect2, varscan2
- PTGFR | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as rs777152890, COSV66114150; called by muse, mutect2, varscan2
- PTGS2 | c.1617A>C p.E539D | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66569086; called by muse, mutect2, varscan2
- RAB30 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565267609, COSV52626525; called by muse, mutect2, varscan2
- RAD54L2 | c.2533C>T p.Q845* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV56578325; called by muse, mutect2, varscan2
- RASEF | c.1200C>T p.D400= | Splice Region (SNP) | VAF 24/65 reads (37%) | catalogued as rs368791188; called by muse, mutect2, varscan2
- RBMXL2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100182191, COSV60981799; called by muse, mutect2, varscan2
- RCC1 | c.1176G>T p.M392I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100868098; called by muse, mutect2, varscan2
- REG3G | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV55448596, COSV55449296; called by muse, mutect2, varscan2
- RELN | c.8140C>G p.H2714D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV100633354; called by muse, mutect2, varscan2
- RELN | c.8139C>A p.F2713L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100633358; called by muse, mutect2, varscan2
- RIPPLY2 | c.174G>T p.A58= | Splice Region (SNP) | VAF 10/22 reads (45%) | catalogued as COSV63762603; called by muse, mutect2
- RNF113A | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 135/387 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV65097295; called by muse, mutect2, varscan2
- RNF17 | c.2555G>T p.S852I | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55039303; called by muse, mutect2, varscan2
- RNF212 | c.743C>T p.T248I (on ENST00000433731 / NM_001366918.1; = p.H230= on NM_194439.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV101260209; called by muse, mutect2, varscan2
- ROBO4 | c.2485G>T p.G829W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60623599; called by muse, mutect2, varscan2
- RP2 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54461628; called by muse, mutect2, varscan2
- RRM2 | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.091); catalogued as rs1351093744, COSV58816648; called by muse, mutect2, varscan2
- RRP1B | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV61478991; called by muse, mutect2, varscan2
- RTL3 | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as COSV58184039; called by muse, mutect2, varscan2
- RYR3 | c.8839C>A p.L2947M (on ENST00000389232; = p.L2948M on NM_001036.6) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV66786748; called by muse, mutect2, varscan2
- SAMD7 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100156863; called by muse, mutect2, varscan2
- SAMD7 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100156868; called by muse, mutect2, varscan2
- SEC24D | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758910502, COSV54879301; called by muse, mutect2, varscan2
- SEMA3D | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV52387611, COSV52392338; called by muse, mutect2
- SERPINA5 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 92/148 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61574039; called by muse, mutect2, varscan2
- SERPINB7 | c.222A>T p.S74= | Splice Region (SNP) | VAF 7/94 reads (7%) | catalogued as rs1465118489, COSV60533660; called by muse, mutect2
- SF3A1 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372226997, COSV99305707; called by muse, mutect2, varscan2
- SGCZ | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.164); catalogued as COSV101166522, COSV66013593; called by muse, mutect2, varscan2
- SHPRH | c.2296G>C p.D766H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51608636, COSV51610260; called by muse, mutect2, varscan2
- SHROOM4 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV56788587; called by muse, mutect2, varscan2
- SIGLEC6 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV58433822; called by muse, mutect2, varscan2
- SIM2 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1289473098, COSV51768367; called by muse, mutect2, varscan2
- SKIDA1 | c.1646G>T p.R549M | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV71610887; called by muse, mutect2, varscan2
- SLAMF7 | c.54A>T p.T18= | Splice Region (SNP) | VAF 54/129 reads (42%) | catalogued as COSV100833277, COSV63563169; called by muse, mutect2, varscan2
- SLC12A5 | c.2909C>T p.A970V (on ENST00000454036 / NM_001134771.2; = p.A947V on NM_020708.5) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV51644085; called by muse, mutect2, varscan2
- SLC12A6 | c.2770A>T p.M924L (on ENST00000354181 / NM_001365088.1; = p.M873L on NM_005135.2) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV51625647; called by muse, mutect2, varscan2
- SLC24A5 | c.533C>G p.A178G | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as COSV58317287; called by muse, mutect2, varscan2
- SLC35D3 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100090472; called by muse, mutect2, varscan2
- SLC6A5 | c.2022C>A p.N674K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV54226000; called by muse, mutect2, varscan2
- SLC9B1 | c.111A>T p.K37N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV56469733; called by muse, mutect2, varscan2
- SLCO1B3 | c.1154C>G p.T385R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV53936798; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2048G>T p.G683V (on ENST00000540229 / NM_001371097.1; = p.G622V on NM_001009562.4) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1028101721, COSV67443300; called by muse, mutect2, varscan2
- SLCO6A1 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV65809197; called by muse, mutect2, varscan2
- SLFN5 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100249651; called by muse, mutect2, varscan2
- SNRNP200 | c.5092G>T p.D1698Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV60489572; called by muse, mutect2, varscan2
- SNTG1 | c.1343G>C p.S448T | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.039); catalogued as COSV52440782; called by muse, mutect2
- SOAT2 | c.1135C>A p.R379= | Splice Region (SNP) | VAF 51/125 reads (41%) | catalogued as COSV56859358; called by muse, mutect2, varscan2
- SOGA1 | c.1829A>C p.Q610P | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV52917409; called by muse, mutect2
- SORCS1 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV53838420, COSV53862485; called by muse, mutect2, varscan2
- SPAG17 | c.4457G>A p.R1486K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV60457860; called by muse, mutect2, varscan2
- SPANXN2 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 202/666 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs782045608, COSV65127788; called by muse, varscan2
- SPTA1 | c.5014G>C p.D1672H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV100935356, COSV63752374; called by muse, mutect2, varscan2
- SPTA1 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 10/244 reads (4%) | catalogued as COSV100934743, COSV63756879; called by muse, mutect2
- SPTA1 | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100934745, COSV63750989; called by muse, mutect2
- SPTBN5 | c.3892A>T p.R1298W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58020014; called by muse, mutect2
- ST6GAL2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | PolyPhen possibly damaging (0.51); catalogued as rs1486948627, COSV64527996; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV60330322; called by muse, mutect2, varscan2
- STAM | c.653T>A p.I218K | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV101092244; called by muse, mutect2, varscan2
- STK39 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596508; called by muse, mutect2, varscan2
- SULT1B1 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100150212, COSV100150430; called by muse, mutect2, varscan2
- SYCP3 | c.107G>C p.S36T | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV57148927; called by muse, mutect2
- SYT9 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 122/272 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV59617697, COSV59622192; called by muse, mutect2, varscan2
- TANC1 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); catalogued as COSV55087157; called by muse, mutect2, varscan2
- TAP2 | c.1742A>T p.Q581L | Missense Mutation (SNP) | VAF 142/195 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV66499042; called by muse, mutect2, varscan2
- TBATA | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs755138847, COSV54718462, COSV54718900; called by muse, mutect2, varscan2
- TBX18 | c.1727A>T p.H576L | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV63736679; called by muse, mutect2, varscan2
- TBXT | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51617593; called by muse, mutect2, varscan2
- TCL1A | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs953278120, COSV68085453; called by muse, mutect2, varscan2
- TFRC | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776805794, COSV64054648; called by muse, mutect2, varscan2
- THOC2 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV55545098; called by muse, mutect2
- TIMELESS | c.3024A>T p.Q1008H | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57511038; called by muse, mutect2, varscan2
- TLR7 | c.1645T>A p.F549I | Missense Mutation (SNP) | VAF 232/652 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as COSV66124204; called by muse, mutect2, varscan2
- TMEFF1 | c.561-1G>T p.X187_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | catalogued as COSV58492996; called by muse, mutect2, varscan2
- TMEM178A | c.401-1G>T p.X134_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV56141725; called by muse, mutect2, varscan2
- TMEM200A | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV51652472; called by muse, mutect2, varscan2
- TMPRSS6 | c.2204G>T p.R735L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60977639; called by muse, mutect2
- TMTC1 | c.2263C>A p.R755S (on ENST00000539277 / NM_001193451.2; = p.R647S on NM_175861.3) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV55480312, COSV55488026; called by muse, mutect2, varscan2
- TMTC1 | c.854G>A p.W285* (on ENST00000539277 / NM_001193451.2; = p.W177* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV55480319; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.46T>C p.C16R | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs1437027847, COSV59528543; called by muse, mutect2, varscan2
- TNXB | c.8581A>T p.T2861S (on ENST00000647633; = p.T2614S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/94 reads (79%) | SIFT tolerated (0.45); PolyPhen benign (0.253); catalogued as COSV64478271; called by muse, mutect2, varscan2
- TP53BP1 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV99780313; called by muse, mutect2, varscan2
- TRAF3IP3 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as COSV50552434; called by muse, mutect2, varscan2
- TRIM29 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs373220023, COSV59281084; called by muse, mutect2, varscan2
- TRIM69 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as COSV57803617; called by muse, mutect2, varscan2
- TRIM72 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs749674647, COSV57251010; called by muse, mutect2, varscan2
- TRPC3 | c.578C>T p.A193V (on ENST00000379645 / NM_001366479.2; = p.A120V on NM_003305.2) | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.822); catalogued as COSV53374945; called by muse, mutect2, varscan2
- TRPC5 | c.2029T>C p.F677L | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1269395065, COSV53289472; called by muse, mutect2
- TRPM2 | c.2140A>T p.K714* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV55969128; called by muse, mutect2, varscan2
- TSPAN33 | c.103-1G>T p.X35_splice | Splice Site (SNP) | VAF 53/168 reads (32%) | catalogued as COSV56826250; called by muse, mutect2, varscan2
- TSPYL2 | c.1415T>G p.I472S | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as rs1556808397, COSV64921060; called by muse, mutect2, varscan2
- TTC12 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59097641; called by muse, mutect2, varscan2
- TTC3 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV61289736; called by muse, mutect2, varscan2
- TTF2 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV65632495; called by muse, mutect2
- TTN | c.53143G>T p.E17715* (on ENST00000591111; = p.E10291* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV60021500; called by muse, mutect2, varscan2
- TTN | c.52712G>T p.G17571V (on ENST00000591111; = p.G10147V on NM_003319.4) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | PolyPhen probably damaging (1); catalogued as COSV60021546; called by muse, mutect2, varscan2
- TTN | c.33958G>T p.G11320C (on ENST00000591111; = p.G10393C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | PolyPhen benign (0.009); catalogued as COSV100606344; called by muse, mutect2, varscan2
- TTN | c.32257G>T p.V10753L (on ENST00000591111; = p.V9826L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | PolyPhen benign (0); catalogued as COSV60021594; called by muse, mutect2, varscan2
- UBA6 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV59176736; called by muse, mutect2, varscan2
- UBASH3A | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV52312196; called by muse, mutect2, varscan2
- UCK2 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV100902928; called by muse, mutect2, varscan2
- UGT2B15 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1001229556, COSV57733718, COSV57734263; called by muse, mutect2, varscan2
- UGT3A2 | c.1082C>A p.P361Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56930305; called by muse, mutect2, varscan2
- UNC5C | c.1383C>A p.D461E | Missense Mutation (SNP) | VAF 83/308 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs761581481, COSV71659267; called by muse, varscan2
- UNC5D | c.2118C>A p.Y706* | Nonsense Mutation (SNP) | VAF 96/223 reads (43%) | catalogued as COSV54790554; called by muse, mutect2, varscan2
- UNC80 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs201833017, COSV55890016, COSV99780038; called by muse, mutect2, varscan2
- UPF3B | c.460A>T p.I154F | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52229909; called by muse, mutect2, varscan2
- USH2A | c.731del p.G244Vfs*13 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | catalogued as COSV56447140; called by mutect2, pindel, varscan2
- USP4 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55536644; called by muse, mutect2, varscan2
- VANGL2 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs768600299, COSV100925559, COSV63604380; called by muse, mutect2, varscan2
- VILL | c.1617_1619del p.F539del | In Frame Del (DEL) | VAF 14/83 reads (17%) | catalogued as rs773733435; called by pindel, varscan2
- VN1R2 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as COSV100447867; called by muse, mutect2, varscan2
- VPS13C | c.10819C>T p.R3607C (on ENST00000644861 / NM_020821.3; = p.R3564C on NM_017684.5) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149574145; called by muse, mutect2, varscan2
- WASF3 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs930323228, COSV58965203; called by muse, mutect2, varscan2
- WDFY3 | c.2430-1G>T p.X810_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV55699854; called by muse, mutect2, varscan2
- WDR35 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55602420; called by muse, mutect2, varscan2
- WNT16 | c.237G>T p.Q79H (on ENST00000222462 / NM_057168.2; = p.Q69H on NM_016087.2) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99743065; called by muse, mutect2, varscan2
- XIRP2 | c.3072C>A p.S1024R (on ENST00000628543; = p.S1199R on NM_152381.6) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54697097; called by muse, mutect2, varscan2
- ZC3H13 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV54452741, COSV54455496; called by muse, mutect2, varscan2
- ZFP30 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV63622582; called by muse, mutect2, varscan2
- ZFPM2 | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 196/379 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV65873399; called by muse, mutect2, varscan2
- ZIC3 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.081); catalogued as COSV54973830; called by muse, varscan2
- ZNF107 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV61326678; called by muse, mutect2, varscan2
- ZNF157 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100998481; called by muse, mutect2, varscan2
- ZNF214 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 29/139 reads (21%) | catalogued as COSV53481396; called by muse, mutect2, varscan2
- ZNF223 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 70/258 reads (27%) | catalogued as COSV71571873; called by muse, mutect2, varscan2
- ZNF227 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV57312189; called by muse, mutect2, varscan2
- ZNF234 | c.2013C>A p.H671Q | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1050437493, COSV70603219; called by muse, mutect2, varscan2
- ZNF423 | c.3027G>C p.E1009D (on ENST00000563137 / NM_001379286.1; = p.E1001D on NM_015069.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV52186583; called by muse, mutect2
- ZNF438 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV59194609; called by muse, mutect2, varscan2
- ZNF454 | c.569G>T p.S190I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV60768224; called by muse, mutect2, varscan2
- ZNF521 | c.2691G>T p.M897I | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV64126319; called by muse, mutect2, varscan2
- ZNF618 | c.2150G>T p.R717L (on ENST00000374126 / NM_001318042.2; = p.R624L on NM_133374.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV55922326; called by muse, mutect2
- ZNF626 | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1555769527, COSV74129420; called by muse, mutect2, varscan2
- ZNF638 | c.1505G>T p.S502I | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV52486447; called by muse, mutect2, varscan2
- ZNF680 | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1339306632, COSV100549085; called by muse, mutect2, varscan2
- ZNF831 | c.4608G>C p.E1536D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV64039680; called by muse, mutect2, varscan2
- ZP4 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63911807; called by muse, mutect2, varscan2
- ZPLD1 | c.76T>A p.C26S (on ENST00000466937 / NM_001329788.1; = p.C42S on NM_175056.2) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60353251; called by muse, mutect2, varscan2
- ZSCAN22 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61639046; called by muse, mutect2, varscan2
- ZWILCH | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV57179614; called by muse, mutect2, varscan2
- ZXDB | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV100885883; called by mutect2, varscan2
- DCLK1 | c.717del p.K240Nfs*3 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | called by mutect2, pindel, varscan2
- GDF10 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GPC6 | c.607_619del p.V203* | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- GRIN3A | c.2520C>A p.D840E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2
- IGHV1OR21-1 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- IL22RA2 | c.79dup p.E27Gfs*63 | Frame Shift Ins (INS) | VAF 25/132 reads (19%) | called by mutect2, pindel, varscan2
- MYH1 | c.3952del p.E1318Nfs*2 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | called by mutect2, pindel, varscan2
- MYOF | c.504del p.P169Qfs*17 | Frame Shift Del (DEL) | VAF 148/428 reads (35%) | called by mutect2, pindel, varscan2
- NELL1 | c.1720del p.H574Tfs*29 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- NOMO2 | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- NTRK2 | c.933del p.K312Nfs*13 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- PALB2 | c.2622del p.M875Cfs*14 | Frame Shift Del (DEL) | VAF 18/162 reads (11%) | called by mutect2, varscan2
- PAPPA2 | c.519del p.T174Pfs*7 | Frame Shift Del (DEL) | VAF 47/172 reads (27%) | called by mutect2, pindel, varscan2
- PGAP4 | c.1082del p.G361Afs*10 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.2308del p.D770Tfs*7 | Frame Shift Del (DEL) | VAF 28/61 reads (46%) | called by mutect2, pindel*, varscan2
- SI | c.2007del p.Q670Rfs*20 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- SI | c.119-3del | Splice Region (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by mutect2, varscan2
- SYT16 | c.1675del p.R559Vfs*33 | Frame Shift Del (DEL) | VAF 29/51 reads (57%) | called by mutect2, varscan2
- TANC1 | c.1443del p.S482Lfs*14 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- TRBV3-1 | c.62C>A p.T21K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZFHX4 | c.5714del p.R1905Kfs*42 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel
- ZNF100 | c.1388del p.G463Afs*10 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, pindel, varscan2
- ABCC11 | c.1221C>A p.S407= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV62321896, COSV62322825; called by muse, mutect2, varscan2
- APOB | c.5751C>G p.L1917= | Silent (SNP) | VAF 97/301 reads (32%) | catalogued as rs543623037, COSV51933806; called by muse, mutect2, varscan2
- ASPH | c.858T>C p.N286= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV62859004; called by muse, mutect2
- ASXL3 | c.3195G>T p.R1065= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV52457217, COSV52463812; called by muse, mutect2, varscan2
- ATRNL1 | c.1560C>A p.A520= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100744935; called by muse, mutect2
- BCL9 | c.2343C>A p.P781= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1553205061, COSV99324922; called by muse, mutect2, varscan2
- C6orf118 | c.270C>A p.R90= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV57814583, COSV57816797; called by muse, mutect2, varscan2
- CCDC191 | c.1794A>T p.A598= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as COSV55671871; called by muse, mutect2, varscan2
- CCNB3 | c.2376G>A p.A792= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs374751350, COSV52072747; called by muse, mutect2
- CD28 | c.609C>G p.R203= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100142338; called by muse, mutect2, varscan2
- CD72 | c.18C>A p.T6= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV52410962; called by muse, mutect2, varscan2
- CDH20 | c.1158C>A p.P386= | Silent (SNP) | VAF 29/260 reads (11%) | catalogued as COSV53009006, COSV99404753; called by muse, mutect2, varscan2
- CFAP44 | c.2622G>T p.V874= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs1445900488, COSV55610990; called by muse, mutect2
- CLDN2 | c.60C>A p.G20= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as COSV61020805; called by muse, mutect2, varscan2
- CSMD3 | c.9357C>T p.T3119= (on ENST00000297405 / NM_001363185.1; = p.T2950= on NM_052900.3) | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV52167249, COSV99831897; called by muse, varscan2
- CTNNA2 | c.81G>T p.L27= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV63563287; called by muse, mutect2, varscan2
- CUL4B | c.372C>A p.T124= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV60687039; called by muse, mutect2, varscan2
- CUX2 | c.324G>A p.A108= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs372659202; called by muse, mutect2, varscan2
- DACT1 | c.1260G>A p.S420= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs755583995, COSV60019599; called by muse, mutect2
- DHCR7 | c.1260G>T p.L420= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV62795059; called by muse, mutect2, varscan2
- DNAH11 | c.8523C>T p.S2841= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV60953771; called by muse, mutect2, varscan2
- DNAH2 | c.954T>C p.F318= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs1409486663, COSV50014305; called by muse, mutect2, varscan2
- DNAH7 | c.246C>T p.S82= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV56762710; called by muse, mutect2, varscan2
- DNAH9 | c.12322C>T p.L4108= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV52347331; called by muse, mutect2, varscan2
- DNAI3 | c.249A>T p.A83= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV54002161; called by muse, mutect2, varscan2
- DRD3 | c.261A>T p.V87= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV55679974; called by muse, mutect2, varscan2
- DUSP9 | c.649C>A p.R217= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV61437940; called by muse, mutect2, varscan2
- EPHA5 | c.150C>A p.L50= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV56642935; called by muse, mutect2, varscan2
- FAM71C | c.132C>A p.P44= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV100175726; called by muse, mutect2, varscan2
- FBXO39 | c.1281G>T p.L427= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV58621751; called by muse, mutect2, varscan2
- FGD5 | c.1248G>A p.V416= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV53241888; called by muse, mutect2, varscan2
- FGF13 | c.177G>T p.P59= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as COSV65434187, COSV65435980; called by muse, varscan2
- GJC2 | c.270C>T p.P90= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs12075149; called by muse, varscan2
- GLRA2 | c.798G>T p.L266= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as COSV54340031; called by muse, mutect2, varscan2
- GMPS | c.958C>A p.R320= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs771766942, COSV55809243; called by muse, mutect2, varscan2
- GPR12 | c.867C>A p.P289= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV67344300; called by muse, mutect2, varscan2
- GRWD1 | c.1194C>T p.P398= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs759264780, COSV53518270; called by muse, mutect2, varscan2
- HCFC1 | c.5217G>T p.T1739= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs782448816, COSV100128505; called by muse, mutect2
- HDAC9 | c.1761G>T p.V587= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101286702, COSV101287163; called by muse, mutect2, varscan2
- HMGCS2 | c.696A>T p.G232= | Silent (SNP) | VAF 39/61 reads (64%) | catalogued as COSV65567801; called by muse, mutect2, varscan2
- HMX2 | c.276C>A p.P92= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100378731, COSV60592395; called by muse, mutect2, varscan2
- HOXD10 | c.648G>A p.V216= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99981896; called by muse, mutect2
- ICA1L | c.1389G>A p.L463= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV64173326; called by muse, mutect2, varscan2
- IFI27L1 | c.141A>T p.A47= | Silent (SNP) | VAF 57/95 reads (60%) | catalogued as COSV67628613; called by muse, mutect2, varscan2
- IGHV4-31 | c.114C>T p.S38= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs1567337159, rs745610242; called by muse, mutect2
- IGLC7 | c.219C>T p.S73= | Silent (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- IKBKG | c.138C>A p.G46= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV99682412; called by muse, mutect2, varscan2
- INSC | c.372G>T p.L124= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV65408772; called by muse, mutect2, varscan2
- IRS4 | c.93C>A p.T31= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV64533591; called by muse, mutect2, varscan2
- ITGB8 | c.1623G>T p.V541= | Silent (SNP) | VAF 53/221 reads (24%) | catalogued as COSV56007802; called by muse, mutect2, varscan2
- IWS1 | c.1755G>T p.L585= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV54868154; called by muse, mutect2, varscan2
- IYD | c.18C>T p.P6= | Silent (SNP) | VAF 127/317 reads (40%) | catalogued as rs770847661, COSV99989567; called by muse, mutect2, varscan2
- KIAA2026 | c.1617G>A p.Q539= | Silent (SNP) | VAF 79/151 reads (52%) | catalogued as COSV67354599; called by muse, mutect2, varscan2
- KIF4B | c.2226A>T p.R742= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV70529110; called by muse, mutect2, varscan2
- KL | c.1848G>A p.L616= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV66308661; called by muse, mutect2, varscan2
- KLHL1 | c.1023A>T p.I341= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV64771651; called by muse, mutect2, varscan2
- KRT28 | c.180C>T p.S60= | Silent (SNP) | VAF 51/85 reads (60%) | catalogued as COSV60684968, COSV60686113; called by muse, mutect2, varscan2
- LAMA3 | c.8325A>C p.G2775= (on ENST00000313654 / NM_198129.4; = p.G1166= on NM_000227.6) | Silent (SNP) | VAF 47/422 reads (11%) | catalogued as COSV52534014; called by muse, mutect2, varscan2
- LHX1 | c.636G>A p.Q212= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, varscan2
- LRRN3 | c.864G>A p.E288= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV57819332; called by muse, mutect2, varscan2
- MAP3K10 | c.918C>T p.I306= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs556924077, COSV53421543; called by muse, mutect2, varscan2
- MAST1 | c.963C>A p.P321= | Silent (SNP) | VAF 59/90 reads (66%) | catalogued as COSV52246132; called by muse, mutect2, varscan2
- MDN1 | c.2613G>T p.L871= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV65520997; called by muse, varscan2
- MED15 | c.1515A>T p.S505= (on ENST00000263205 / NM_001003891.3; = p.S465= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99487605; called by muse, mutect2, varscan2
- MRC1 | c.1264T>C p.L422= | Silent (SNP) | VAF 272/557 reads (49%) | called by muse, mutect2, varscan2
- MTMR1 | c.1212G>C p.V404= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV64892403; called by muse, mutect2, varscan2
- MUC17 | c.10632C>A p.S3544= | Silent (SNP) | VAF 119/387 reads (31%) | catalogued as COSV60287248; called by muse, mutect2, varscan2
- MYO7B | c.258G>T p.L86= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV101268083; called by muse, mutect2, varscan2
- NLGN4X | c.2052G>A p.S684= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs745730856, COSV52015727; called by muse, mutect2, varscan2
- NLRP13 | c.2841C>A p.A947= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV61621477; called by muse, mutect2, varscan2
- OCRL | c.1302G>A p.E434= | Silent (SNP) | VAF 88/271 reads (32%) | catalogued as COSV63980787; called by muse, mutect2, varscan2
- OR2B11 | c.555G>T p.V185= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs140643495, COSV100275794; called by muse, varscan2
- OR2B3 | c.105C>T p.Y35= | Silent (SNP) | VAF 64/87 reads (74%) | catalogued as COSV101013778; called by muse, mutect2, varscan2
- OR3A2 | c.78A>T p.L26= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV101375051; called by muse, mutect2, varscan2
- OR51F2 | c.717C>A p.A239= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV59064568; called by muse, mutect2, varscan2
- OR51Q1 | c.789T>A p.T263= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as COSV56178727; called by muse, mutect2, varscan2
- PALLD | c.1845C>T p.P615= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV54979647, COSV99825139; called by muse, mutect2, varscan2
- PASK | c.1767G>T p.G589= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV52151972; called by muse, mutect2, varscan2
- PCLO | c.7836T>C p.D2612= | Silent (SNP) | VAF 79/183 reads (43%) | catalogued as COSV61632133; called by muse, mutect2, varscan2
- PDZD8 | c.1866G>T p.V622= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV57825223; called by muse, mutect2, varscan2
- PIGV | c.63G>T p.L21= | Silent (SNP) | VAF 44/69 reads (64%) | catalogued as COSV99314878; called by muse, mutect2, varscan2
- PIK3CG | c.33G>C p.V11= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV63247971; called by muse, mutect2, varscan2
- PJA1 | c.1539C>T p.L513= (on ENST00000361478 / NM_145119.4; = p.L325= on NM_022368.5) | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV64053029; called by muse, varscan2
- PKNOX2 | c.282C>A p.T94= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV53545080; called by muse, mutect2, varscan2
- POTEH | c.171C>A p.L57= | Silent (SNP) | VAF 103/878 reads (12%) | catalogued as COSV58882331; called by muse, varscan2
- PRAME | c.987A>T p.I329= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as COSV67161479; called by muse, mutect2, varscan2
- PROKR2 | c.744G>T p.R248= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV54086327; called by muse, mutect2, varscan2
- PTPRB | c.1848C>T p.G616= | Silent (SNP) | VAF 75/172 reads (44%) | catalogued as COSV54239465; called by muse, mutect2, varscan2
- PTPRB | c.1230C>A p.I410= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV54239480, COSV99716277; called by muse, varscan2
- RAB33A | c.489C>A p.S163= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99924525; called by muse, mutect2, varscan2
- RAG1 | c.2326C>A p.R776= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as CM090373, COSV55024503, COSV55025002; called by muse, mutect2, varscan2
- RAG2 | c.771T>C p.S257= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs1450589029, COSV100271224; called by muse, mutect2, varscan2
- RBMXL2 | c.891G>T p.G297= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100182105, COSV100182195; called by muse, mutect2, varscan2
- RFT1 | c.309C>A p.I103= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV56248749; called by muse, mutect2, varscan2
- RYR1 | c.8250G>A p.K2750= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV62096015; called by muse, mutect2, varscan2
- SAMD4A | c.2013C>G p.S671= | Silent (SNP) | VAF 64/382 reads (17%) | catalogued as COSV51880177; called by muse, mutect2, varscan2
- SEM1 | c.180A>G p.L60= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs202151961, COSV50350975; called by muse, mutect2, varscan2
- SIGLEC6 | c.1248C>A p.P416= | Silent (SNP) | VAF 106/329 reads (32%) | catalogued as COSV58433806; called by muse, mutect2, varscan2
- SLC14A2 | c.1755C>A p.L585= | Silent (SNP) | VAF 134/182 reads (74%) | catalogued as COSV54908571; called by muse, mutect2, varscan2
- SLC18A2 | c.933G>T p.L311= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV53690289; called by muse, mutect2, varscan2
- SLC22A12 | c.978G>A p.E326= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV60571920; called by muse, mutect2, varscan2
- SLC45A2 | c.1275G>T p.L425= | Silent (SNP) | VAF 74/188 reads (39%) | catalogued as COSV56871436; called by muse, mutect2, varscan2
- SLITRK1 | c.379C>T p.L127= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV65673997; called by muse, mutect2, varscan2
- SLITRK3 | c.1902G>T p.G634= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV53846628, COSV53848043; called by muse, mutect2
- SORCS3 | c.1404G>A p.G468= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV63809064; called by muse, mutect2, varscan2
- STAM | c.654A>T p.I218= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV101092246; called by muse, mutect2, varscan2
- TAF3 | c.222G>T p.G74= | Silent (SNP) | VAF 66/239 reads (28%) | catalogued as COSV60206204, COSV60210878; called by muse, mutect2, varscan2
- THSD7A | c.649C>A p.R217= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV70264212; called by muse, mutect2, varscan2
- TIAM1 | c.2928C>T p.T976= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs557120271, COSV54548964; called by muse, mutect2, varscan2
- TLR4 | c.1974G>T p.L658= (on ENST00000355622 / NM_138554.5; = p.L618= on NM_003266.4) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV62923157; called by muse, mutect2, varscan2
- TMEM131L | c.4182C>T p.P1394= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs543922994, COSV53643894; called by muse, mutect2, varscan2
- TMEM144 | c.1008A>G p.G336= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV56700725; called by muse, mutect2, varscan2
- TNR | c.267G>A p.Q89= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV54883213; called by muse, mutect2, varscan2
- TNXB | c.12189C>T p.I4063= (on ENST00000647633; = p.I3816= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV64478261; called by muse, mutect2
- TP53BP1 | c.693G>A p.Q231= | Silent (SNP) | VAF 76/186 reads (41%) | catalogued as rs1215173177, COSV99780309; called by muse, mutect2, varscan2
- TRBV29-1 | c.210C>T p.A70= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs754848052; called by muse, mutect2, varscan2
- TRO | c.1215C>A p.T405= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV51500878; called by muse, mutect2
- UCK2 | c.708G>T p.R236= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100902931; called by muse, mutect2, varscan2
- UNC13C | c.5508T>C p.S1836= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52868128; called by muse, mutect2, varscan2
- USH2A | c.4770G>A p.V1590= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as rs546481031, COSV56362948; called by muse, mutect2, varscan2
- USP36 | c.357C>T p.R119= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs747490867, COSV61751505; called by muse, mutect2, varscan2
- UTP20 | c.1347C>A p.L449= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV55376286; called by muse, mutect2, varscan2
- WDR90 | c.1632C>T p.D544= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV53469251; called by muse, mutect2
- WNK3 | c.651A>G p.L217= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV63613564; called by muse, mutect2, varscan2
- ZBTB41 | c.393A>T p.V131= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV66359087; called by muse, mutect2, varscan2
- ZFPM2 | c.672G>C p.L224= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV65873195, COSV65873395; called by muse, mutect2, varscan2
- ZNF862 | c.3495C>T p.A1165= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1468236020, COSV56223774; called by muse, mutect2, varscan2
- CLCN5 | c.17-33828C>A | Intron (SNP) | VAF 65/177 reads (37%) | catalogued as COSV65801104; called by muse, mutect2, varscan2
- DENND10P1 | n.1173C>A | RNA (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85893G>T | Intron (SNP) | VAF 40/158 reads (25%) | catalogued as COSV72276871; called by muse, mutect2, varscan2
- MAST4 | c.674+59272G>T | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as COSV101282530; called by muse, mutect2, varscan2
- OR52A4P | n.975G>T | RNA (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-21309G>C | Intron (SNP) | VAF 90/265 reads (34%) | catalogued as rs754565791; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100157615 C>A | 3'Flank (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- SDHC | c.*109T>A | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- SSX6P | n.113A>T | RNA (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- STMP1 | chr7:135660371 G>T | 5'Flank (SNP) | VAF 79/185 reads (43%) | called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1373G>T | RNA (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- TIPIN | c.475+1795G>T | Intron (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99972347; called by muse, mutect2, varscan2
- ZNF783 | c.802+3364G>T | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100954217; called by muse, mutect2
